Somatic mutation profile of tumor specimen TCGA-EB-A82C-01A (aliquot TCGA-EB-A82C-01A-11D-A34U-08) from TCGA case TCGA-EB-A82C, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 70.8 years (25,863 days).
Specimen TCGA-EB-A82C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3fc6748-1b29-4e06-a4c6-064c85af5372.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A82C-10B (Blood Derived Normal), aliquot TCGA-EB-A82C-10B-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c27a5683-ace3-49e5-a552-09abd7b6d623

The open-access MAF lists 36 somatic variants for this specimen: 25 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 19, Silent 11, Nonsense Mutation 4, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 40/59 reads (68%) | catalogued as rs55861249, CM960096, COSV53734495; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 20/28 reads (71%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- ADGRV1 | c.11431G>A p.D3811N | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV101316275, COSV67994217; called by muse, mutect2, varscan2
- ASL | c.1262C>T p.S421L | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs148669165; called by muse, mutect2, varscan2
- B4GAT1 | c.1097T>G p.L366R | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100240350; called by muse, mutect2, varscan2
- CAD | c.2867T>G p.V956G | Missense Mutation (SNP) | VAF 60/77 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99255459; called by muse, mutect2, varscan2
- CUL1 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100296833, COSV100296860; called by muse, mutect2, varscan2
- ERBB4 | c.2581G>A p.D861N | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV61471534, COSV61535377; called by muse, mutect2, varscan2
- GIP | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs761410381, COSV100656966; called by muse, mutect2, varscan2
- GRIK1 | c.1502A>G p.D501G | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100517515; called by muse, mutect2, varscan2
- LAMA5 | c.2207C>A p.A736D | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV99441410; called by muse, mutect2, varscan2
- MARCHF1 | c.487G>A p.V163I (on ENST00000274056; = p.V146I on NM_017923.4) | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs752184817, COSV99919754; called by muse, mutect2, varscan2
- MRGPRX1 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.243); catalogued as rs1309719773, COSV57107643; called by muse, mutect2
- MYO5B | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 38/176 reads (22%) | catalogued as COSV99545913; called by muse, mutect2, varscan2
- NYAP2 | c.38A>G p.E13G | Missense Mutation (SNP) | VAF 51/82 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99797877; called by muse, mutect2, varscan2
- OFD1 | c.2487A>G p.E829= | Splice Region (SNP) | VAF 47/107 reads (44%) | catalogued as COSV100407050; called by muse, mutect2, varscan2
- OR10W1 | c.817A>G p.T273A | Missense Mutation (SNP) | VAF 63/118 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs1427962663, COSV101223764; called by muse, mutect2, varscan2
- OR51B5 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs533818406, COSV56175748; called by muse, mutect2, varscan2
- PLCB4 | c.3308G>T p.R1103L | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as rs775720888; called by muse, mutect2
- PTGER3 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 21/107 reads (20%) | catalogued as rs750859595, COSV100139412; called by muse, mutect2, varscan2
- PTPRH | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 41/218 reads (19%) | catalogued as rs767269805, COSV99671300; called by muse, mutect2, varscan2
- SCLY | c.809G>A p.G270D (on ENST00000651534; = p.G262D on NM_016510.7) | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99616075; called by muse, mutect2, varscan2
- SCN9A | c.4496G>A p.R1499Q (on ENST00000303354; = p.R1488Q on NM_002977.3) | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs372320353, COSV57612842; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNJ1 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as rs146507597; called by muse, mutect2, varscan2
- UBR1 | c.1523T>G p.I508S | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV99317640; called by muse, mutect2, varscan2
- ACSM3 | c.621C>T p.N207= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as rs750454982, COSV99184795; called by muse, mutect2, varscan2
- ATG4A | c.441A>T p.G147= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV100619824; called by muse, mutect2, varscan2
- GPR50 | c.198C>T p.F66= | Silent (SNP) | VAF 113/301 reads (38%) | catalogued as COSV54439024; called by muse, mutect2, varscan2
- LILRB1 | c.1140G>A p.L380= (on ENST00000427581; = p.L344= on NM_006669.6) | Silent (SNP) | VAF 9/115 reads (8%) | catalogued as COSV100207630; called by muse, mutect2
- MED12 | c.3819C>A p.A1273= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100379226; called by muse, mutect2, varscan2
- RCOR2 | c.648G>A p.E216= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV100036310; called by muse, mutect2, varscan2
- SHE | c.1485C>T p.H495= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV100496139; called by muse, mutect2
- SYNE2 | c.8016C>T p.L2672= | Silent (SNP) | VAF 48/136 reads (35%) | catalogued as COSV100648218; called by muse, mutect2, varscan2
- TMEM176B | c.489G>T p.V163= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV100423644; called by muse, mutect2, varscan2
- UBR1 | c.1524T>A p.I508= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV99317637; called by muse, mutect2, varscan2
- ZNF519 | c.516T>C p.H172= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV101645582; called by muse, mutect2, varscan2
